Somatic mutation profile of tumor specimen C3N-02783-05 (aliquot CPT0205890009) from CPTAC case C3N-02783, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 24.3 years (8,889 days).
Specimen C3N-02783-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f35fd1d-c9fe-446c-9313-bfaf73b71975.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02783-71 (Blood Derived Normal), aliquot CPT0205950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbd6d9ec-3724-4861-8543-36ac83017502

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Nonsense Mutation 2, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 12/140 reads (9%) | hotspot (GDC flag); catalogued as COSV64870748; called by muse, mutect2
- KRTAP4-16 | c.517G>C p.V173L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated, low confidence (0.61); catalogued as rs543735212; called by muse, varscan2
- OSBPL5 | c.1244+1G>T p.X415_splice | Splice Site (SNP) | VAF 9/96 reads (9%) | catalogued as rs1377094525; called by muse, mutect2
- RNF114 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1236575131; called by muse, mutect2, varscan2
- SVIL | c.5080G>A p.G1694R (on ENST00000355867 / NM_021738.3; = p.G1268R on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs780319605, COSV100881710, COSV63448110; called by muse, mutect2, varscan2
- TRIM64C | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs779694861; called by muse, mutect2
- ADAM33 | c.1629G>T p.Q543H | Missense Mutation (SNP) | VAF 19/428 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.2); called by muse, mutect2
- DCHS2 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 42/426 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB10 | c.534T>A p.Y178* | Nonsense Mutation (SNP) | VAF 71/247 reads (29%) | called by muse, mutect2, varscan2
- NRXN3 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN3 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 48/378 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, varscan2
- FKBPL | c.411G>A p.P137= | Silent (SNP) | VAF 95/345 reads (28%) | catalogued as rs975859579; called by muse, mutect2, varscan2
